Surgical pathology report (de-identified scan), TCGA case TCGA-61-1901, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-61-1901-01A (Primary Tumor).

FINAL DIAGNOSIS:

PART 1: OVARY, RIGHT, OOPHORECTOMY –

- A. PAPILLARY SEROUS CARCINOMA, HIGH-GRADE.
- B. LYMPHOVASCULAR SPACE INVASION IDENTIFIED.

PART 2: TUBE AND OVARY, LEFT, SALPINGOOOPHORECTOMY –

- A. PAPILLARY SEROUS CARCINOMA, HIGH-GRADE, INVOLVING TUBE AND OVARY.
- B. TUBAL INTRAEPITHELIAL CARCINOMA.
- C. LYMPHOVASCULAR SPACE INVASION IDENTIFIED.

PART 3: UTERUS WITH RIGHT TUBE, TOTAL ABDOMINAL HYSTERECTOMY AND RIGHT SALPINGECTOMY –

- A. PAPILLARY SEROUS CARCINOMA INVOLVING UTERINE SEROSA AND FALLOPIAN TUBE.
- B. LYMPHOVASCULAR SPACE INVASION IDENTIFIED.
- C. INACTIVE ENDOMETRIUM.
- D. CHRONIC CERVICITIS.

PART 4: LYMPH NODE, RIGHT PELVIC, EXCISION –

- A. METASTATIC PAPILLARY SEROUS CARCINOMA INVOLVING ONE OF ONE LYMPH NODE (1/1).
- B. THE METASTATIC FOCUS MEASURES 1.3 CM IN LARGEST DIMENSION.
- C. NO EXTRACAPSULAR EXTENSION IDENTIFIED.

PART 5: OMENTUM, OMENECTOMY –

- A. METASTATIC CARCINOMA INVOLVING OMENTAL ADIPOSE TISSUE.
- B. THE METASTATIC FOCUS MEASURES 1.0 CM IN LARGEST DIMENSION.

PART 6: "BOWEL TUMOR", EXCISION –

METASTATIC CARCINOMA INVOLVING FIBROADIPOSE TISSUE.

PART 7: "CUL-DE-SAC TUMOR", EXCISION –

METASTATIC CARCINOMA INVOLVING FIBROUS TISSUE.

CASE SYNOPSIS:

SYNOPTIC - PRIMARY OVARIAN TUMORS INCLUDING BORDERLINE TUMORS

TUMOR LOCATION:	Bilateral
PROCEDURE:	Bilateral Salpingo-oophorectomy
TUMOR SIZE:	Maximum dimension: 12 cm
TUMOR TYPE:	Papillary serous carcinoma
VASCULAR INVASION:	Yes
TUMOR CAPSULE:	Ruptured
SURFACE IMPLANTS:	Invasive
MALIGNANT CELLS IN ASCITES OR PERITONEAL WASHING:	Yes
LYMPH NODES EXAMINED:	Total number of lymph nodes examined: 1
LYMPH NODES POSITIVE:	Number of positive lymph nodes, Right: 1
LYMPH NODE GROUPS INVOLVED:	Pelvic, Right
T STAGE, PATHOLOGIC:	pT3
N STAGE, PATHOLOGIC:	pN1
M STAGE, PATHOLOGIC:	pM1
FIGO STAGE:	IV

Source: NCI Genomic Data Commons file 40999a77-1b53-4d66-b44e-3e781ee727c5 (TCGA-61-1901.BF0681BA-341E-4C73-8081-7400740FFCB3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).